TCGA case TCGA-3B-A9HZ — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/32377dd2-c2a2-44ff-8938-b8cfb35db79c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Alive.

Diagnoses (4)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C49.3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of thorax; Classification of tumor: primary; Age at diagnosis: 66.9 years (24,433 days); Year of diagnosis: 2011; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Sites of involvement: Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis percent: 20; Necrosis present: Yes.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 6.9; Tumor length measurement: 8.5; Tumor width measurement: 4.5.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 6; Tumor length measurement: 9.5; Tumor width measurement: 7.5.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 67.7 years (24,742 days); Days to diagnosis: 309 days; Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 1.7; Tumor width measurement: 1.8.
3. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 67.7 years (24,742 days); Days to diagnosis: 309 days; Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 0.7.
4. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Pelvis, NOS. Age at diagnosis: 68.4 years (24,979 days); Days to diagnosis: 546 days (1.5 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 2.6; Tumor width measurement: 2.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 1.8; Tumor width measurement: 1.6.

Follow-up (4 entries)
- Day 309 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 309 days; Discontiguous lesion count: 6.
- Day 546 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pelvis, NOS; Days to progression: 546 days (1.5 years).
- Days to follow up: 943 days (2.6 years); Disease response: With Tumor.
- Days to follow up: 1,170 days (3.2 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3B-A9HZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-3B-A9HZ-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3B-A9HZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3B-A9HZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Positive; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Lung; Contiguous organ invaded: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Chest - Mediastinum.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic depth: 6.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 482; Days from index date to pharmaceutical treatment ended: 602; Pharmaceutical therapy drug name: Docetaxel; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 482; Days from index date to pharmaceutical treatment ended: 602; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 834; Days from index date to pharmaceutical treatment ended: 889; Pharmaceutical therapy drug name: Pazopanib; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 4: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 906; Days from index date to pharmaceutical treatment ended: 1164; Pharmaceutical therapy drug name: Docetaxel; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 5: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 906; Days from index date to pharmaceutical treatment ended: 1164; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Days from index date to radiation therapy started: 118; Days from index date to radiation therapy ended: 144; Radiation therapy type: External; Radiation total dose: 6000; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 30; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,170 days; disease-specific survival: no event (censored), 1,170 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 309 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3B-A9HZ-01A-11D-A38Y-01): tumor purity 0.7, ploidy 1.86, whole-genome doublings 0.
